TCGA case TCGA-39-5027 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dd7eda40-9aae-46b2-914e-788b76b43087

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 73.1 years (26,714 days); Year of diagnosis: 2006; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 3,108 days (8.5 years); Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Subsequent primary (histology not recorded by GDC). Age at diagnosis: 81.6 years (29,795 days); Days to diagnosis: 3,081 days (8.4 years); Prior treatment: Yes.

Follow-up (3 entries)
- Days to follow up: 1,849 days (5.1 years); Disease response: Tumor Free.
- Days to follow up: 3,108 days (8.5 years); Disease response: With Tumor.
- ECOG performance status: 2; Timepoint: Other.

Other clinical attributes
- DLCO (% of predicted): 79; FEV1/FVC after bronchodilator (%): 82; FEV1/FVC before bronchodilator (%): 78; FEV1 after bronchodilator (% of reference): 63; FEV1 before bronchodilator (% of reference): 55.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Tobacco smoking onset year: 1946; Tobacco smoking quit year: 2002.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-39-5027-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.8; Intermediate dimension: 1.3; Shortest dimension: 0.4.
  Slide TCGA-39-5027-01A-01-BS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 65; Percent normal cells: 30; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-39-5027-01A-02-BS2: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 55; Percent normal cells: 40; Percent necrosis: 5; Percent stromal cells: 5.
- Sample TCGA-39-5027-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-39-5027-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1.7; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; Tumor status: With tumor.
- Follow-up form 2, New neoplasm event types: New tumor event type: New Primary Tumor.
- Follow-up form 2, Progression determined by list: New tumor event diagnosis evidence: Biopsy with Histologic Confirmation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,108 days; disease-specific survival: no event (censored), 3,108 days; disease-free interval: no event (censored), 3,108 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 3,081 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-39-5027-01): tumor purity 0.68, ploidy 1.79, whole-genome doublings 0 (call status: maf_call).
